Gene-level copy-number profile of tumor specimen TCGA-D6-A6EM-01A from TCGA case TCGA-D6-A6EM, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 65.3 years (23,865 days).
Specimen TCGA-D6-A6EM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.39dfda29-0ee5-443c-adc3-7e04fd37cc57.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D6-A6EM-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c59ab9c8-ed04-432e-b8cf-40fa6cbb2644

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3; copy number 2: 1,102; copy number 4: 22,686; copy number 5: 537; copy number 6: 25,452; copy number 7: 3,332; copy number 8: 3,679; copy number 9: 1,681; copy number 10: 935; copy number 11: 409.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D6-A6EM-01A-21D-A31K-01): tumor purity 0.32, ploidy 2.75, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
